Surgical pathology report (de-identified scan), TCGA case TCGA-IN-AB1X, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-IN-AB1X-01A (Primary Tumor).

[page 1 of 6]
ICD-O-3

Adenocarcinoma NOS 8140/3
Site Gastroesophageal junction C16.0
JDS 4/25/14

Anonymous number:

Accession Date:

Collection Date:

FINAL DIAGNOSIS:

PART 10: SOFT TISSUE, LEFT GASTRIC, EXCISION -
TWO (2) ANTHRACOTIC LYMPH NODES, NEGATIVE FOR METASTATIC CARCINOMA.
PART 2: LYMPH NODE, INFERIOR PULMONARY LIGAMENT, EXCISION -
ONE (1) ANTHRACOTIC LYMPH NODE, NEGATIVE FOR METASTATIC CARCINOMA.
PART 3: LYMPH NODE, LEVEL 7 NEAR BRONCHUS INTERMEDIUS, EXCISION -
ONE (1) ANTHRACOTIC LYMPH NODE, NEGATIVE FOR METASTATIC CARCINOMA.
PART 4: LYMPH NODE, NEAR PERICARDIUM, EXCISION -
ONE (1) MINUTE ANTHRACOTIC LYMPH NODE FRAGMENT, NEGATIVE FOR METASTATIC CARCINOMA.
PART 5: LYMPH NODE, NEAR LEFT MAINSTEM, EXCISION -
ONE (1) ANTHRACOTIC LYMPH NODE, NEGATIVE FOR METASTATIC CARCINOMA.
PART 6: LYMPH NODE, PARAESOPHAGEAL NEAR LUNG, EXCISION -
A. ONE (1) LYMPH NODE FRAGMENT WITH MINUTE HYALINIZED NODULE, NEGATIVE FOR METASTATIC CARCINOMA.
B. AFB AND GMS ARE NEGATIVE FOR FUNGAL ORGANISMS.
PART 7: LYMPH NODE, LEVEL 7 NEAR AORTA, EXCISION -
TWO (2) ANTHRACOTIC LYMPH NODE FRAGMENTS, NEGATIVE FOR METASTATIC CARCINOMA.
PART 8: LYMPH NODE, LEVEL 7 NEAR LEFT DISTAL MAINSTEM, EXCISION -
ONE (1) ANTHRACOTIC LYMPH NODE, NEGATIVE FOR METASTATIC CARCINOMA.
PART 9: LYMPH NODE, SUBCARINAL, EXCISION -
TWO (2) ANTHRACOTIC LYMPH NODE FRAGMENTS, NEGATIVE FOR METASTATIC CARCINOMA.
PART 10: LYMPH NODE, SUBCARINAL ON ESOPHAGUS, EXCISION -
ONE (1) ANTHRACOTIC LYMPH NODE, NEGATIVE FOR METASTATIC CARCINOMA.
PART 11: LYMPH NODE, SUBCARINAL NEAR AZYGOUS, EXCISION -
ONE (1) ANTHRACOTIC LYMPH NODE, NEGATIVE FOR METASTATIC CARCINOMA.
PART 12: ESOPHAGUS AND STOMACH, ESOPHAGOGASTRECTOMY -
A. INVASIVE POORLY DIFFERENTIATED ADENO CARCINOMA WITH SQUAMOUS DIFFERENTIATION, INVOLVING GASTROESOPHAGEAL JUNCTION, 2.2 CM.
B. CARCINOMA INVADES FOCALLY THROUGH MUSCULARIS PROPRIA INTO SUBADVENTITIAL TISSUE.
C. NEGATIVE FOR LYMPHVASCULAR SPACE INVASION.

Per JSS, approximated
5% squamous
differentiation

[page 2 of 6]
Anonymous No.:

Age: █

Gender: F

Race: White

CLINICAL HISTORY

PRE-OP DIAGNOSIS: Esophageal cancer

POST-OP DIAGNOSIS: Same/ pending

PROCEDURE: Esophagogastroduodenoscopy, bronchoscopy, laparoscopic staging, MIV IVOR, laparoscopic Lewis esophagectomy

FINAL DIAGNOSIS

PART 10: SOFT TISSUE, LEFT GASTRIC, EXCISION

TWO (2) ANTHRACOTIC LYMPH NODES, NEGATIVE FOR METASTATIC CARCINOMA.

PART 2: LYMPH NODE, INFERIOR PULMONARY LIGAMENT, EXCISION

ONE (1) ANTHRACOTIC LYMPH NODE, NEGATIVE FOR METASTATIC CARCINOMA.

PART 3: LYMPH NODE, LEVEL 7 NEAR BRONCHUS INTERMEDIUS, EXCISION

ONE (1) ANTHRACOTIC LYMPH NODE, NEGATIVE FOR METASTATIC CARCINOMA.

PART 4: LYMPH NODE, NEAR PERICARDIUM, EXCISION

ONE (1) MINUTE ANTHRACOTIC LYMPH NODE FRAGMENT, NEGATIVE FOR METASTATIC CARCINOMA.

PART 5: LYMPH NODE, NEAR LEFT MAINSTEM, EXCISION

ONE (1) ANTHRACOTIC LYMPH NODE, NEGATIVE FOR METASTATIC CARCINOMA.

PART 6: LYMPH NODE, PARAESOPHAGEAL NEAR LUNG, EXCISION

A. ONE (1) LYMPH NODE FRAGMENT WITH MINUTE HYALINIZED NODULE, NEGATIVE FOR METASTATIC CARCINOMA.

B. AFB AND GMS ARE NEGATIVE FOR FUNGAL ORGANISMS.

PART 7: LYMPH NODE, LEVEL 7 NEAR AORTA, EXCISION

TWO (2) ANTHRACOTIC LYMPH NODE FRAGMENTS, NEGATIVE FOR METASTATIC CARCINOMA.

PART 8: LYMPH NODE, LEVEL 7 NEAR LEFT DISTAL MAINSTEM, EXCISION

ONE (1) ANTHRACOTIC LYMPH NODE, NEGATIVE FOR METASTATIC CARCINOMA.

PART 9: LYMPH NODE, SUBCARINAL, EXCISION

TWO (2) ANTHRACOTIC LYMPH NODE FRAGMENTS, NEGATIVE FOR METASTATIC CARCINOMA.

PART 10: LYMPH NODE, SUBCARINAL ON ESOPHAGUS, EXCISION

ONE (1) ANTHRACOTIC LYMPH NODE, NEGATIVE FOR METASTATIC CARCINOMA.

PART 11: LYMPH NODE, SUBCARINAL NEAR AZYGIOUS, EXCISION

[page 3 of 6]
ONE (1) ANTHRACOTIC LYMPH NODE, NEGATIVE FOR METASTATIC CARCINOMA.

PART 12: ESOPHAGUS AND STOMACH, ESOPHAGOGASTRECTOMY

A. INVASIVE POORLY DIFFERENTIATED ADENO CARCINOMA WITH SQUAMOUS *per TSS, Squamous = 5%* DIFFERENTIATION,

INVOLVING GASTROESOPHAGEAL JUNCTION, 2.2 CM.

B. CARCINOMA INVADES FOCALLY THROUGH MUSCULARIS PROPRIA INTO SUBADVENTITIAL TISSUE.

C. NEGATIVE FOR LYMPHVASCULAR SPACE INVASION.

D. TWENTY FIVE LYMPH NODES, NEGATIVE FOR METASTATIC CARCINOMA (0/25).

E. MARGINS NEGATIVE FOR CARCINOMA.

F. AJCC 7TH EDITION PATHOLOGIC TUMOR STAGE IS: pT3 N0.

PART 13: LYMPH NODE, PROXIMAL PARAESOPHAGEAL, EXCISION

ONE (1) ANTHRACOTIC LYMPH NODE, NEGATIVE FOR METASTATIC CARCINOMA.

PART 14: LYMPH NODE, MID PARAESOPHAGEAL, EXCISION

ONE (1) ANTHRACOTIC LYMPH NODE, NEGATIVE FOR METASTATIC CARCINOMA.

PART 15: LYMPH NODE, PARAESOPHAGEAL NEAR DIAPHRAGM, EXCISION

SCANT FRAGMENT OF ANTHRACOTIC LYMPH NODE, NEGATIVE FOR METASTATIC CARCINOMA.

PART 16: ANASTOMOTIC RING, ESOPHAGOGASTRECTOMY

BENIGN SQUAMOUS AND GASTRIC MARGINS.

PART 17: FINAL GASTRIC MARGIN, ESOPHAGOGASTRECTOMY

BENIGN GASTRIC MARGIN.

PART 18: OMENTUM, OMENTECTOMY

BENIGN FIBROADIPOSE TISSUE, NEGATIVE FOR METASTATIC CARCINOMA.

COMMENT

██████████ reviewed select slides from part 12 and agrees with the above interpretation.

GROSS DESCRIPTION

The specimen is received in 18 parts.

Part 1 is received in formalin labeled with the patient name, initials █████ and "left gastric tissue". The specimen consists of two portions of yellow fatty tissue, the larger is 2.5 x 1.4 x 0.3 cm. No lesions are seen or palpated. The smaller portion of tissue is 0.7 x 0.5 x 0.3 cm. No lesions are seen or palpated. The specimen is entirely submitted in a cassette labeled 1A.

1A x 2, entirely submitted

Part 2 is received in formalin labeled with the patient name, initials █████ and "inferior pulmonary ligament node". The specimen consists of a black nodule, 0.7 x 0.7 x 0.6 cm. The specimen is bisected and the cut surface has a homogenous black appearance. The specimen is entirely submitted in a cassette labeled 2A.

[page 4 of 6]
2A x 2, entirely submitted

Part 3 is received in formalin labeled with the patient name, initials [REDACTED] and "level 7 LN near bronchus intermedius". The specimen consists of an irregular portion of black soft tissue, 1.0 x 0.5 x 0.3 cm. The specimen is entirely submitted in a cassette labeled 3A.

3A x 1, entirely submitted

Part 4 is received in formalin labeled with the patient name, initials [REDACTED] and "lymph node near pericardium". The specimen consists of a tiny black fragment of soft tissue, 0.1 cm in greatest dimension. The specimen is entirely submitted in a cassette labeled 4A.

4A x 1, entirely submitted

Part 5 is received in formalin labeled with the patient name, initials [REDACTED] and "lymph node near left mainstem". The specimen consists of a fragment of gray-tan soft tissue, 0.3 x 0.2 x 0.1 cm. The specimen is entirely submitted in a cassette labeled 5A.

5A x 1, entirely submitted

Part 6 is received in formalin labeled with the patient name, initials [REDACTED] and "paraesophageal lymph node near lung". The specimen consists of a black nodule, 0.6 x 0.5 x 0.1 cm. The specimen consists of a black nodule, 0.6 x 0.5 x 0.1 cm. The specimen is entirely submitted in a cassette labeled 6A.

6A x 1, entirely submitted

Part 7 is received in formalin labeled with the patient name, initials [REDACTED] and "level 7 LN near aorta". The specimen consists of two black portions of soft tissue, the larger is 0.7 x 0.5 x 0.4 cm, the smaller is 0.4 x 0.2 x 0.2 cm. The specimen is entirely submitted in a cassette labeled 7A.

7A x 2, entirely submitted

Part 8 is received in formalin labeled with the patient name, initials [REDACTED] and "level 7 near distal left mainstem". The specimen consists of a black nodule, 0.6 x 0.6 x 0.3 cm. The specimen is entirely submitted in a cassette labeled 8A.

8A x 1, entirely submitted

Part 9 is received in formalin labeled with the patient name, initials [REDACTED] and "subcarinal lymph node". The specimen consists of four yellow-black portions of soft tissue, the largest is 0.7 x 0.7 x 0.3 cm, the smallest is 0.5 x 0.3 x 0.2 cm. The specimen is entirely submitted in a cassette labeled 9A.

9A x 4, entirely submitted

Part 10 is received in formalin labeled with the patient name, initials [REDACTED] and "subcarinal lymph node on esophagus". The specimen consists of a black nodule, 1.0 x 0.9 x 0.4 cm. The cut surface has a homogenous black appearance. The specimen is entirely submitted in a cassette labeled 10A.

10A x 1, entirely submitted

Part 11 is received in formalin labeled with the patient name, initials [REDACTED] and "subcarinal lymph node near azygous". The specimen consists of a black nodule, 1.4 x 1.0 x 0.5 cm. The cut surface reveals a homogenous black appearance. The specimen is bisected and entirely submitted in a cassette labeled 11A.

11A x 2, entirely submitted

Part 12 is received fresh labeled with the patient name, initials [REDACTED] and "esophagogastrctomy". The specimen consists of a portion of esophagus and stomach. The esophagus is 8.0 cm in length. The esophageal margin 6.5 cm in circumference. The

[page 5 of 6]
stomach is up to 6.8 cm in length. The gastric margin is 11.0 cm in circumference. Located in the esophagus, 6.0 cm from the esophageal resection edge is an ulcerated gray-white lesion, 2.2 x 2.0 x 0.7 cm. This grossly involves the gastroesophageal junction. It is also 5.5 cm away from the closest gastric margin. The esophageal margin and the gastric margin were used for frozen section. On sectioning the lesion extends into the muscularis but not through the entire thickness of the muscularis. Remaining esophageal mucosa has a gray-white appearance. The gastric mucosa is red-tan. The attached fat is 5.5 x 4.0 x 2.5 cm. Serial sectioning reveals multiple pink-tan and red-tan nodules within the fat, the largest is 0.9 x 0.4 x 0.3 cm, the smallest is 0.3 x 0.4 x 0.2 cm. Representative sections are submitted labeled:

12AFS x 1, esophageal margin used for frozen section
12BFS x 1, gastric margin used for frozen section
12C-12D x 1 each, remainder of the gastric margin taken as a shave
12E-12K x 1 each, lesion, entirely submitted
12L-12M x 1 each, esophagus proximal to the lesion
12N-12O x 1 each, stomach distal to the lesion
12P-12R x multiple each, lymph nodes
12S-12Al x multiple each, fat entirely submitted

The soft tissues beneath the lesion are painted with blue ink.

Part 13 is received in formalin labeled with the patient name, initials [redacted] and "proximal paraesophageal lymph node". The specimen consists of a black nodule, 0.8 x 0.7 x 0.6 cm. The cut surface reveals a gray-black tissue. The specimen is entirely submitted in a cassette labeled 13A.

13A x 2, entirely submitted

Part 14 is received in formalin labeled with the patient name, initials [redacted] and "mid paraesophageal lymph node". The specimen consists of a pink-tan nodule, 1.3 x 1.0 x 0.3 cm. The specimen is entirely submitted in a cassette labeled 14A.

14A x 1, entirely submitted

Part 15 is received in formalin labeled with the patient name, initials [redacted] and "paraesophageal lymph node near diaphragm". The specimen consists of an irregular portion of gray-black soft tissue, 1.2 x 0.5 x 0.2 cm. The specimen is entirely submitted in a cassette labeled 15A.

15A x 1, entirely submitted

Part 16 is received in formalin labeled with the patient name, initials [redacted] and "anastomotic ring". The specimen consists of two ring-shaped portions of mucosal tissue attached to a metal anvil, each is approximately 1.5 cm in diameter, 1.3 cm in length. On sectioning tissue contains metal staples and sutures. Representative section of each is submitted in a cassette labeled:

16A x 2, soft tissue

Part 17 is received in formalin labeled with the patient name, initials [redacted] and "final gastric margin". The specimen consists of a previously opened portion of stomach, 4.0 cm in length, 3.8 cm in diameter. One edge of the specimen is closed with metal staples. The end opposite this is left open and it contains green sutures and metal staples. The mucosal surface has a pink-tan to red-tan appearance. No lesions are seen.

Representative sections are submitted labeled:

17A x 2, shave of each margin

17B x 2, random section

The stapled margin is painted with blue ink, the open margin is painted with black ink.

Part 18 is received in formalin labeled with the patient name, initials [redacted] and "omentum".

[page 6 of 6]
The specimen consists of lobulated portion of fatty tissue, 7.0 x 3.0 x 0.3 cm. The cut surface reveals a pale yellow tissue. No masses are seen or palpated. The specimen is entirely submitted labeled:

18A-18E x 2 each, entirely submitted

MICROSCOPIC DESCRIPTION

AFB and GMS control slides reacted appropriately. Microscopic examination substantiates the above diagnosis.

INTRAOPERATIVE DIAGNOSIS

~~TEST 6 AND TEST 7~~ ESOPHAGOGASTRECTOMY (FROZEN SECTION)

- A. SUFFICIENT FOR ANCILLARY STUDIES.
- B. DEFER.
- C. GASTRIC AND ESOPHAGEAL MARGINS NEGATIVE.

Reported to [REDACTED] on

by [REDACTED]

Source: NCI Genomic Data Commons file 74c3aee1-b8a1-450e-a049-1a4734c930bf (TCGA-IN-AB1X.03B5A14D-7D7D-4FF2-B41F-E98A2E771E33.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).